Gene-level copy-number profile of tumor specimen TCGA-ZJ-A8QR-01A from TCGA case TCGA-ZJ-A8QR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage I; Tumor grade: GX; Age at diagnosis: 38.9 years (14,225 days).
Specimen TCGA-ZJ-A8QR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.5c3c9472-463e-427a-95ea-24b6a3384993.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZJ-A8QR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32dac987-e30c-47d2-8ad7-2c05dcf7a2ef

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 2; copy number 2: 6,132; copy number 3: 8,594; copy number 4: 40,761; copy number 5: 2,154; copy number 6: 1,121; copy number 7: 960; copy number 9: 17; copy number 11: 6; copy number 21: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZJ-A8QR-01A-11D-A37M-01): tumor purity 0.63, ploidy 3.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:28,349,178–29,767,537, 1 gene (within-gene range 0–2): AC098650.1.
- chr3:28,574,791–30,894,765, 16 genes (within-gene range 0–2): RBMS3, RBMS3-AS3, MESTP4, RPS12P5, RBMS3-AS2, MTND4LP9, RBMS3-AS1, AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr3:60,856,389–60,856,605, 1 gene: U3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 75 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:101,029,624–103,895,271, 57 genes, copy number 11–21: PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693.
- chr11:103,945,548–103,946,546, 1 gene, copy number 21: AP003043.1.
- chr15:65,442,463–65,891,989, 17 genes, copy number 9 (within-gene range 5–9): DPP8, AC105129.3, AC105129.1, Y_RNA, HACD3, RNU6-19P, INTS14, SLC24A1, AC011939.3, DENND4A, SNORD13E, MIR4511, RAB11A, AC011939.2, AC011939.1, HNRNPA1P44, U6.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
